Gene-level copy-number profile of tumor specimen TCGA-CV-7421-01A from TCGA case TCGA-CV-7421, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 76.6 years (27,961 days).
Specimen TCGA-CV-7421-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.12133134-fc9e-4e6c-b706-446f4dd20a70.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-7421-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 831 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e9f10a23-9f98-43a9-889d-4744e87415bb

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 888; copy number 2: 13,779; copy number 3: 20,106; copy number 4: 16,227; copy number 5: 2,035; copy number 6: 2,844; copy number 7: 1,494; copy number 8: 1,053; copy number 9: 60; copy number 10: 679; copy number 11: 83; copy number 12: 227; copy number 13: 58; copy number 14: 229; copy number 19: 30.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-7421-01A-11D-2077-01): tumor purity 0.42, ploidy 3.37, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,913 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:46,429,190–52,407,917, 81 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr2:54,661,011–79,123,409, 468 genes, copy number 7 (broad region; genes not listed).
- chr4:58,780,626–59,630,324, 8 genes, copy number 8–12: AC017091.1, LINC02619, LINC02429, AC097501.1, AC108517.2, AC108517.1, Y_RNA, AC096588.1.
- chr5:58,198–3,601,403, 92 genes, copy number 7 (broad region; genes not listed).
- chr5:13,690,331–14,532,128, 4 genes, copy number 7 (within-gene range 6–7): DNAH5, AC016576.1, TRIO, AC016549.1.
- chr5:39,718,984–41,870,425, 26 genes, copy number 7 (within-gene range 6–7): INTS6P1, GCSHP1, LINC00603, KRT18P56, LINC00604, RNU1-150P, AC108105.1, AC093277.1, AC114977.1, AC114977.2, TTC33, SNORA63, PTGER4, PRKAA1, AC008810.1, RPL37, SNORD72, CARD6, C7, RNU7-161P, AC114967.1, MROH2B, C6, PLCXD3, AC008817.1, OXCT1.
- chr7:75,533,298–107,564,261, 590 genes, copy number 7–13 (within-gene range 5–13) (broad region; genes not listed).
- chr8:42,101,318–145,066,685, 1,588 genes, copy number 8–14 (broad region; genes not listed).
- chr10:81,870,778–82,987,179, 6 genes, copy number 8 (within-gene range 4–8): AL096706.1, NRG3, AC010157.2, AC010157.1, NRG3-AS1, RNU6-441P.
- chr11:121,674,261–122,872,643, 21 genes, copy number 12 (within-gene range 6–12): AP001977.1, AP001924.1, RNU6-256P, AP001924.2, MIR100HG, MIR125B1, BLID, MIRLET7A2, MIR100, AP000755.1, AP000755.2, RNU4ATAC10P, RNU4ATAC5P, RNU6-592P, GLULP3, AP002469.1, UBASH3B, AP002762.3, AP002762.1, AP002762.2, CRTAM.
- chr12:1,380,060–2,697,950, 29 genes, copy number 8 (within-gene range 5–8): AC004672.1, AC004672.2, LINC00942, WNT5B, FBXL14, MIR3649, ADIPOR2, AC005183.1, AC005343.4, RPS4XP14, CACNA2D4, AC005343.7, LRTM2, AC005342.2, LINC00940, DCP1B, CACNA1C, AC005342.1, CACNA1C-IT1, CACNA1C-IT2, AC005344.1, CACNA1C-AS4, CACNA1C-IT3, AC005293.1, AC005414.1, CACNA1C-AS3, AC007618.1, CACNA1C-AS2, CACNA1C-AS1.
- chr14:22,086,407–22,509,406, 66 genes, copy number 7 (broad region; genes not listed).
- chr19:17,555,649–24,163,425, 317 genes, copy number 7–12 (broad region; genes not listed).
- chr19:37,696,371–41,137,308, 180 genes, copy number 8 (within-gene range 4–8) (broad region; genes not listed).
- chr20:31,257,664–31,723,989, 30 genes, copy number 19: DEFB115, DKKL1P1, AL121723.1, DEFB116, RPL31P3, HAUS6P2, RNA5SP480, DEFB117, DEFB118, AL031650.1, DEFB119, DEFB121, DEFB122, DEFB123, DEFB124, REM1, LINC00028, HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON.
- chr20:33,702,758–36,646,196, 109 genes, copy number 7–11 (broad region; genes not listed).
- chr21:15,928,296–16,645,467, 1 gene, copy number 7 (within-gene range 5–7): MIR99AHG.
- chr21:16,284,696–16,873,691, 12 genes, copy number 7: SNORD74B, AP001172.1, AP001172.2, AP000962.3, AP000962.2, MIR99A, MIRLET7C, AP000962.1, MIR125B2, RNU1-98P, AF130359.1, AF212831.1.
- chr21:23,857,081–24,114,352, 5 genes, copy number 9 (within-gene range 3–9): AP000474.2, AP000474.1, AP000477.2, AP000477.3, AP000477.1.
- chr22:19,520,572–22,755,797, 239 genes, copy number 7–9 (broad region; genes not listed).
- chr22:35,992,321–37,007,851, 41 genes, copy number 7: Z82217.1, Z95114.4, Z95114.1, Z95114.2, Z95114.3, APOL3, MTCO1P20, MTCO2P20, MTATP6P20, MTCO3P20, MTCYBP34, MTND1P10, APOL4, APOL2, APOL1, MYH9, MIR6819, Z82215.1, FO393418.1, RPS15AP38, Y_RNA, AL022313.2, TXN2, FOXRED2, EIF3D, AL022313.1, AL022313.3, CACNG2, AL022313.4, AL049749.1, Z80897.2, IFT27, Z80897.1, PVALB, Z82185.1, NCF4-AS1, NCF4, CSF2RB, CSF2RBP1, LL22NC01-81G9.3, TEX33.

Autosomal genes at a single copy (total copy number 1): 888. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
